CCDI case PBBIPL — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b9f124c6-3802-4de9-8b9f-f6adf37a9761

Demographics
Sex at birth: male; Race: black or african american; Vital status: Alive.

Diagnoses (1)
1. Pilocytic astrocytoma: ICD-O-3 morphology code: 9421/1; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 12.0 years (4,377 days).

Biospecimens (3 samples)
- Sample 0DAN60: Tissue type: Normal; Specimen type: Solid Tissue.
- Sample 0DAN6G: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DAN6Q: Tissue type: Tumor; Specimen type: Solid Tissue.
